HCMI case HCM-BROD-0719-C43 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/04c73a4a-8dec-4727-979a-6bc041e5a2f6

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1952; Vital status: Alive.

Diagnoses (2)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C43.9; Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 66.3 years (24,230 days); AJCC staging edition: 8th; AJCC clinical stage: Stage III; AJCC pathologic T: TX; AJCC pathologic N: N3b; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIC; Metastasis at diagnosis: Metastasis, NOS; Prior treatment: No; Sites of involvement: Lymph node, NOS.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Dabrafenib + Trametinib; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 250 days; Days to treatment end: 771 days (2.1 years); Treatment outcome: Treatment Ongoing.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Chemotherapy, for residual disease; adjuvant Hormone Therapy, for residual disease; adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/6; ICD-10 code: C77.3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Lymph node, NOS; Classification of tumor: metastasis; Age at diagnosis: 67.0 years (24,471 days); Days to diagnosis: 241 days; Satellite nodule present: Indeterminate.
   Pathology details: Lymph nodes positive: 13; Lymph nodes tested: 27.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Dabrafenib + Trametinib; Treatment intent type: Maintenance Therapy; Days to treatment start: 262 days; Days to treatment end: 504 days (1.4 years); Treatment outcome: Treatment Ongoing.

Follow-up (3 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 0 days.
- Days to follow up: 771 days (2.1 years); Disease response: Stable Disease; Progression or recurrence: No.
- Follow-up contact recording only the day: day 460.

Molecular and laboratory tests
- BRAF (IHC): Positive; Amino-acid change: V600E.
- BRAF mutation, nos: Positive; Amino-acid change: V600E.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 88 kg; Height: 173 cm; BMI: 29.4.

Exposures
- Tobacco smoking status: Current Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-BROD-0719-C43-06B: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-BROD-0719-C43-06B-01-S1-HE: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 8; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 6.
  Slide HCM-BROD-0719-C43-06B-01-S2-HE: Section location: Bottom; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 9; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 7.
- Sample HCM-BROD-0719-C43-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0719-C43-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 8.
